Gene-level copy-number profile of tumor specimen TCGA-83-5908-01A from TCGA case TCGA-83-5908, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.6 years (21,760 days).
Specimen TCGA-83-5908-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3f0544a7-a6c9-4ba1-bdd8-ba7888b3bab4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-83-5908-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39cb1917-072f-48b6-b73e-d93a8c76069f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,011; copy number 2: 16,770; copy number 3: 18,686; copy number 4: 15,938; copy number 5: 5,267; copy number 6: 401; copy number 7: 859; copy number 8: 174; copy number 9: 250; copy number 11: 193; copy number 12: 267.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-83-5908-01A-21D-2283-01): tumor purity 0.4, ploidy 1.66, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:129,094,749–129,173,257, 3 genes: ISOC1, MIR4633, AC008679.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,743 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–159,203,313, 711 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9–12 (broad region; genes not listed).
- chr9:3,824,127–4,348,392, 1 gene, copy number 7 (within-gene range 4–7): GLIS3.
- chr9:4,299,390–4,679,502, 7 genes, copy number 7: AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT.
- chr12:17,479,446–17,709,867, 1 gene, copy number 8 (within-gene range 1–8): AC048352.1.
- chr12:17,673,299–28,581,511, 173 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:30,861,921–32,383,633, 56 genes, copy number 7: PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2.
- chr12:32,726,383–34,219,246, 27 genes, copy number 7: AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27.
- chr20:37,101,226–38,923,024, 57 genes, copy number 7 (within-gene range 4–7): MROH8, AL031659.1, RPN2, GHRH, MANBAL, AL034422.1, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P.

Autosomal genes at a single copy (total copy number 1): 1,011. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
